Somatic mutation profile of tumor specimen TCGA-BA-A6DA-01A (aliquot TCGA-BA-A6DA-01A-31D-A31L-08) from TCGA case TCGA-BA-A6DA, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Supraglottis; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 41.1 years (15,004 days).
Specimen TCGA-BA-A6DA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edf07afe-22e8-4a24-ab13-f9cfd93888f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-A6DA-10A (Blood Derived Normal), aliquot TCGA-BA-A6DA-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/625b889c-eb09-4b5a-93e7-1fa820a7b620

The open-access MAF lists 777 somatic variants for this specimen: 576 protein-altering or splice-affecting, 182 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 488, Silent 182, Nonsense Mutation 35, Frame Shift Del 25, Splice Site 16, Intron 7, RNA 7, Frame Shift Ins 6, Splice Region 4, 3'Flank 3, 5'UTR 1, 5'Flank 1.

Variants (750 of 777; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.2872C>T p.Q958* | Nonsense Mutation (SNP) | VAF 26/133 reads (20%) | catalogued as rs1057524391, COSV57598421; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGM1 | c.566del p.G189Afs*17 | Frame Shift Del (DEL) | VAF 25/176 reads (14%) | catalogued as rs1211601030; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 16/33 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- A1CF | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99255378; called by muse, mutect2, varscan2
- ABCC12 | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100252229; called by muse, mutect2, varscan2
- ABCC9 | c.1367C>A p.A456E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99684716; called by muse, mutect2, varscan2
- ABCC9 | c.1191G>C p.R397S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV53964491; called by muse, mutect2, varscan2
- ABCC9 | c.652C>A p.P218T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs1362149867, COSV99684720; called by muse, mutect2, varscan2
- ABHD18 | c.940A>T p.K314* (on ENST00000398965 / NM_001039717.2; = p.K221* on NM_025097.2 and 10 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/108 reads (22%) | catalogued as rs756016785, COSV101180682; called by muse, mutect2
- ACE2 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV99382574; called by muse, mutect2, varscan2
- ACSM1 | c.1450G>A p.V484I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV99532594; called by muse, mutect2, varscan2
- ACSS3 | c.1049A>G p.Y350C | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs757224536, COSV54084830; called by muse, mutect2, varscan2
- ACTC1 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.01); catalogued as COSV99291634; called by muse, mutect2, varscan2
- ACVR1C | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 72/274 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as COSV99694389; called by muse, mutect2, varscan2
- ADAM30 | c.1177C>A p.P393T | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV65561179, COSV65561236; called by muse, mutect2, varscan2
- ADAMTS12 | c.3860A>T p.E1287V | Missense Mutation (SNP) | VAF 65/353 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); catalogued as COSV100710369; called by muse, mutect2, varscan2
- ADAMTS12 | c.3074C>A p.P1025H | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV100710371; called by muse, mutect2, varscan2
- ADAMTS12 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 100/260 reads (38%) | catalogued as COSV100710372; called by muse, mutect2, varscan2
- ADAMTS14 | c.661G>T p.G221W | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV64604914; called by muse, mutect2
- ADAMTS14 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100941402; called by muse, mutect2, varscan2
- ADAMTS3 | c.2462C>A p.T821K | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV99710362; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.386A>T p.H129L | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.506); catalogued as COSV100416240; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.869A>G p.Y290C | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.704); catalogued as COSV100416241; called by muse, mutect2, varscan2
- ADGRV1 | c.7285G>A p.V2429I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.145); catalogued as COSV101315543; called by muse, mutect2, varscan2
- ADSS2 | c.1289G>T p.R430L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV100836801, COSV63695060; called by muse, mutect2, varscan2
- AFF2 | c.2812G>T p.G938C | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV99662176; called by mutect2, varscan2
- AFF2 | c.2952C>G p.I984M | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.309); catalogued as COSV99662179; called by muse, mutect2, varscan2
- AFF3 | c.507G>T p.R169S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV100418004; called by muse, mutect2, varscan2
- AGBL1 | c.2480T>C p.V827A | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.105); catalogued as rs778861694, COSV101222313; called by muse, mutect2, varscan2
- AGMO | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV100693705; called by muse, mutect2, varscan2
- AGPS | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99931080; called by muse, mutect2, varscan2
- AGXT | c.488T>A p.L163Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV100279927; called by muse, mutect2, varscan2
- AHCTF1 | c.2890C>A p.P964T (on ENST00000366508; = p.P938T on NM_015446.5) | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.586); catalogued as rs147399261; called by muse, mutect2, varscan2
- ALMS1 | c.7796G>T p.R2599I | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV52509038; called by muse, mutect2, varscan2
- ALMS1 | c.7997A>T p.K2666I | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100041343; called by muse, mutect2, varscan2
- AMPD1 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV100814847; called by muse, mutect2, varscan2
- AMPD1 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV100814850; called by muse, mutect2, varscan2
- ANGPT4 | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101124651, COSV67921606; called by muse, mutect2, varscan2
- ANK2 | c.354G>T p.K118N | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.772); catalogued as COSV100000052; called by muse, mutect2, varscan2
- ANK3 | c.7768G>T p.E2590* | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | catalogued as COSV55057411, COSV99778550; called by muse, mutect2, varscan2
- ANKH | c.432+2T>A p.X144_splice | Splice Site (SNP) | VAF 4/72 reads (6%) | catalogued as COSV99414644; called by muse, mutect2
- ANKRD11 | c.5567G>T p.G1856V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV99968474; called by muse, mutect2, varscan2
- ANKRD11 | c.5380G>T p.D1794Y | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs771309106, COSV56353900, COSV99968477; called by muse, mutect2, varscan2
- ANKRD45 | c.328+2T>A p.X110_splice | Splice Site (SNP) | VAF 15/67 reads (22%) | catalogued as COSV100322383; called by muse, mutect2, varscan2
- ANLN | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56074757, COSV56077152; called by muse, mutect2, varscan2
- ANLN | c.1681A>T p.S561C | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99731957; called by muse, mutect2, varscan2
- APC | c.7633G>T p.G2545* | Nonsense Mutation (SNP) | VAF 21/94 reads (22%) | catalogued as COSV99965731; called by muse, mutect2, varscan2
- APCDD1 | c.251T>G p.V84G | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV100789905; called by muse, varscan2
- APLP1 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as COSV99383635; called by muse, mutect2
- APOB | c.6203C>A p.S2068Y | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV51924830, COSV51925527; called by muse, mutect2, varscan2
- ARFGEF3 | c.1883C>G p.S628* | Nonsense Mutation (SNP) | VAF 59/229 reads (26%) | catalogued as COSV99292517, COSV99294225; called by muse, mutect2, varscan2
- ARHGEF6 | c.1480-1G>T p.X494_splice | Splice Site (SNP) | VAF 21/57 reads (37%) | catalogued as COSV51691753, COSV99166364; called by muse, mutect2, varscan2
- ASCC3 | c.4494C>G p.D1498E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100976261; called by muse, mutect2, varscan2
- ATG2B | c.2923C>A p.P975T | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100737751; called by muse, mutect2, varscan2
- ATP10B | c.2417-2A>C p.X806_splice | Splice Site (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100514281; called by muse, mutect2, varscan2
- ATP1A3 | c.77A>C p.K26T (on ENST00000545399 / NM_001256214.2; = p.K13T on NM_152296.5) | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs782280535, COSV100132019; called by muse, mutect2, varscan2
- ATP1B4 | c.349T>C p.F117L (on ENST00000218008 / NM_001142447.3; = p.F113L on NM_012069.5) | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as COSV99486176; called by muse, mutect2, varscan2
- ATP6V1D | c.382G>C p.G128R | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53599433, COSV99370752; called by muse, mutect2
- BAHCC1 | c.6517C>A p.H2173N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as COSV100311218; called by muse, mutect2, varscan2
- BBX | c.948G>T p.K316N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.312); catalogued as COSV100361114; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4549A>T p.T1517S | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.017); catalogued as COSV100863610; called by muse, mutect2, varscan2
- BMP4 | c.926G>T p.R309L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV99816800, COSV99816993; called by muse, mutect2, varscan2
- BRAT1 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as rs139472984; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRINP1 | c.134G>T p.R45M | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99774635; called by muse, varscan2
- BRINP1 | c.70C>A p.H24N | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); catalogued as COSV56315106; called by muse, varscan2
- BRINP3 | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs1462773787, COSV100818418; called by muse, mutect2, varscan2
- BSX | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1565347536, COSV58005447; called by muse, mutect2, varscan2
- C10orf88 | c.588G>T p.M196I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100924995; called by muse, mutect2, varscan2
- C12orf71 | c.219A>T p.Q73H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.599); catalogued as COSV101460505, COSV70282771; called by muse, mutect2, varscan2
- C20orf194 | c.1116G>T p.Q372H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99330357; called by muse, mutect2, varscan2
- C2orf16 | c.831G>A p.M277I | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV101284341; called by muse, mutect2, varscan2
- C3 | c.1523G>T p.R508L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55580515, COSV55581357, COSV99836146; called by muse, mutect2
- CAB39L | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 28/82 reads (34%) | catalogued as COSV100759514; called by muse, mutect2, varscan2
- CACNA2D2 | c.2389C>T p.H797Y (on ENST00000479441 / NM_001174051.3; = p.H790Y on NM_006030.4) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99816994; called by muse, mutect2, varscan2
- CACNB4 | c.568G>T p.G190W | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99137832; called by muse, mutect2, varscan2
- CACNG7 | c.630C>G p.Y210* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99711865; called by muse, mutect2, varscan2
- CADM3 | c.391C>G p.Q131E (on ENST00000368125 / NM_001127173.3; = p.Q165E on NM_021189.5) | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as COSV100930267; called by muse, varscan2
- CALCB | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100158027; called by muse, mutect2, varscan2
- CAMTA1 | c.3460C>T p.R1154W | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771725138, COSV100346722; called by muse, mutect2, varscan2
- CARMIL2 | c.2278G>T p.E760* | Nonsense Mutation (SNP) | VAF 24/94 reads (26%) | catalogued as COSV100575967; called by muse, mutect2, varscan2
- CCDC102B | c.1053G>T p.E351D | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as rs1345938014, COSV100102420; called by muse, mutect2, varscan2
- CCDC105 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs1389047048, COSV99479751; called by muse, mutect2, varscan2
- CCDC47 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV99854011; called by muse, mutect2, varscan2
- CCDC47 | c.1035G>T p.E345D | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV56722996; called by muse, mutect2, varscan2
- CCDC80 | c.1217G>T p.R406M | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV99244368; called by muse, mutect2, varscan2
- CDCA8 | c.232G>T p.G78* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100523522; called by muse, mutect2, varscan2
- CDH12 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV101201715; called by muse, mutect2
- CDK5RAP2 | c.2959C>T p.Q987* | Nonsense Mutation (SNP) | VAF 91/183 reads (50%) | catalogued as COSV100575159; called by muse, mutect2, varscan2
- CDKL5 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV101184080; called by muse, mutect2, varscan2
- CDKN2A | c.295del p.R99Gfs*47 | Frame Shift Del (DEL) | VAF 33/76 reads (43%) | catalogued as CM045408, CM056555, COSV58704101, COSV58726012; called by mutect2, pindel, varscan2
- CEACAM8 | c.518A>G p.N173S | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.084); catalogued as COSV99747448; called by muse, mutect2, varscan2
- CECR2 | c.2749C>A p.P917T (on ENST00000342247 / NM_001290047.2; = p.P734T on NM_001290046.1) | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.522); catalogued as COSV99377207; called by muse, mutect2, varscan2
- CEP83 | c.1133G>C p.R378P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100352674, COSV60406717; called by muse, mutect2, varscan2
- CEP85L | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.52); catalogued as COSV100821001; called by muse, mutect2, varscan2
- CES2 | c.1579G>T p.G527C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100399088; called by muse, mutect2, varscan2
- CETN2 | c.242C>G p.T81R | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV100938608; called by muse, mutect2, varscan2
- CFAP65 | c.2165C>T p.P722L | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.187); catalogued as COSV100444712, COSV58568247; called by muse, mutect2, varscan2
- CFH | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV100661324; called by muse, mutect2, varscan2
- CFH | c.965-2A>T p.X322_splice | Splice Site (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100661326; called by muse, mutect2
- CHD7 | c.3886G>C p.D1296H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV101418029; called by muse, mutect2, varscan2
- CHD8 | c.2945A>G p.N982S (on ENST00000646647 / NM_001170629.2; = p.N703S on NM_020920.4) | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101303051; called by muse, mutect2, varscan2
- CHRD | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99200248; called by muse, mutect2, varscan2
- CHST10 | c.430G>C p.A144P | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.478); catalogued as COSV99958716; called by muse, mutect2, varscan2
- CIR1 | c.190G>T p.V64L | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV100564881; called by muse, mutect2, varscan2
- CLCNKA | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV100509901, COSV100510380; called by muse, mutect2, varscan2
- CMYA5 | c.4468A>G p.R1490G | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1466513471, COSV101483889; called by muse, mutect2, varscan2
- COL11A1 | c.4274C>G p.A1425G | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100615376; called by muse, mutect2
- COL22A1 | c.4006G>A p.G1336R | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV100276640; called by muse, mutect2
- CPE | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101291551; called by muse, mutect2, varscan2
- CPEB1 | c.1852C>T p.R618W (on ENST00000617958; = p.R553W on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1567161437; called by muse, varscan2
- CPSF1 | c.3356G>A p.G1119D | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as rs1224655385, COSV100450239; called by muse, mutect2, varscan2
- CREB3L3 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs534584711, COSV50247174; called by muse, mutect2, varscan2
- CSMD2 | c.6050C>T p.P2017L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.309); catalogued as rs1172998957, COSV53908812; called by muse, mutect2, varscan2
- CSMD3 | c.11105C>T p.T3702M (on ENST00000297405 / NM_001363185.1; = p.T3533M on NM_052900.3) | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1163363504, COSV52203591; called by muse, mutect2, varscan2
- CSMD3 | c.1376T>A p.F459Y (on ENST00000297405 / NM_001363185.1; = p.F355Y on NM_052900.3) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV99826470; called by muse, mutect2
- CUBN | c.1765G>T p.E589* | Nonsense Mutation (SNP) | VAF 25/105 reads (24%) | catalogued as COSV100912161; called by muse, mutect2, varscan2
- CUX2 | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); catalogued as COSV99918786; called by muse, varscan2
- CYLC1 | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV100254132, COSV61415669; called by muse, mutect2, varscan2
- DAAM2 | c.1108A>C p.T370P | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99224790; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | catalogued as rs751187768; called by mutect2, varscan2
- DBX1 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as COSV99910118; called by muse, mutect2
- DBX1 | c.468A>C p.P156= | Splice Region (SNP) | VAF 11/86 reads (13%) | catalogued as COSV99910120; called by muse, mutect2
- DCAF8L1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369821812, COSV101491402; called by muse, mutect2, varscan2
- DCX | c.46A>G p.R16G | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as COSV100576214; called by muse, mutect2
- DCX | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.174); catalogued as COSV100576215; called by muse, mutect2
- DEK | c.59A>T p.E20V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV99788718; called by muse, mutect2, varscan2
- DIP2C | c.3589T>A p.Y1197N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99790275; called by muse, mutect2, varscan2
- DLG3 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99529233; called by muse, mutect2, varscan2
- DLGAP3 | c.2477C>A p.P826H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs766718999, COSV99332246; called by muse, mutect2, varscan2
- DLX5 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as COSV56033455, COSV99756250; called by muse, mutect2, varscan2
- DMWD | c.1483A>T p.S495C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99352785; called by muse, mutect2
- DNA2 | c.2683C>T p.L895F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100622400; called by muse, mutect2, varscan2
- DNAH11 | c.2653C>A p.H885N | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV100177554; called by muse, mutect2, varscan2
- DNAH5 | c.10930G>T p.G3644* | Nonsense Mutation (SNP) | VAF 16/139 reads (12%) | catalogued as COSV54218549; called by muse, mutect2, varscan2
- DNAH7 | c.6578C>G p.S2193* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100414090; called by muse, mutect2, varscan2
- DNAH8 | c.9310G>A p.E3104K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs200884766, COSV59426129; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNHD1 | c.347C>A p.P116H | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99599520; called by muse, mutect2, varscan2
- DPF1 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100831427; called by muse, mutect2, varscan2
- DPP10 | c.2292G>C p.K764N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.06); catalogued as COSV100059726; called by muse, mutect2, varscan2
- DPPA2 | c.718C>G p.R240G | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs748847987, COSV101524741, COSV72118040; called by muse, mutect2, varscan2
- DSEL | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100025340; called by muse, mutect2, varscan2
- DTX4 | c.1049G>T p.R350M | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99915071; called by muse, mutect2
- DYSF | c.3220C>G p.L1074V | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as CD1414197, COSV99244779; called by muse, mutect2, varscan2
- EFNA1 | c.454+1G>A p.X152_splice | Splice Site (SNP) | VAF 17/88 reads (19%) | catalogued as COSV57598225; called by muse, mutect2, varscan2
- EIF4G2 | c.2533A>G p.K845E | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100379394; called by muse, mutect2, varscan2
- EIF4G3 | c.4573G>A p.A1525T | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV99943405; called by muse, mutect2, varscan2
- ELMO1 | c.1764C>A p.Y588* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100163519; called by muse, mutect2, varscan2
- ENOX1 | c.906G>T p.Q302H | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs568201241, COSV99815168; called by muse, mutect2, varscan2
- EP300 | c.4230G>T p.R1410S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV54329554; called by muse, mutect2, varscan2
- EPAS1 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1464807024, COSV99762960; called by muse, mutect2, varscan2
- EPHA6 | c.2358C>G p.I786M (on ENST00000389672 / NM_001080448.3; = p.I178M on NM_173655.4) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101061009; called by muse, mutect2, varscan2
- EPHA8 | c.2244G>T p.M748I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV99384336; called by muse, mutect2
- EPX | c.245C>A p.A82D | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.475); catalogued as COSV99836282; called by muse, mutect2, varscan2
- ERAP2 | c.1018G>A p.G340S | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101163515; called by muse, mutect2, varscan2
- ERICH3 | c.2788G>T p.E930* | Nonsense Mutation (SNP) | VAF 32/157 reads (20%) | catalogued as COSV100443555, COSV58604453; called by muse, mutect2, varscan2
- ERMARD | c.908G>A p.R303K | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs772948421, COSV100824533; called by muse, mutect2, varscan2
- FAM3A | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV100453583; called by muse, mutect2, varscan2
- FAT4 | c.3670G>T p.A1224S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.11); catalogued as COSV101272052; called by muse, mutect2, varscan2
- FAT4 | c.10574C>T p.P3525L | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.393); catalogued as COSV100627380; called by muse, mutect2, varscan2
- FERMT2 | c.728T>C p.L243P | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.817); catalogued as COSV100448734; called by muse, mutect2, varscan2
- FGF23 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV99426276; called by muse, mutect2, varscan2
- FGF23 | c.140C>G p.A47G | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.586); catalogued as COSV99426280; called by muse, mutect2, varscan2
- FKBP9 | c.1610T>C p.I537T | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.041); catalogued as rs774844987, COSV99639029; called by muse, mutect2, varscan2
- FLNA | c.3577C>G p.L1193V | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV100774332; called by muse, mutect2, varscan2
- FLNA | c.1065+1G>T p.X355_splice | Splice Site (SNP) | VAF 15/101 reads (15%) | catalogued as CS1511627, CS1511628, COSV100774333; called by muse, mutect2, varscan2
- FSHR | c.1415C>G p.T472R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100436649, COSV100437020, COSV58622557; called by muse, mutect2, varscan2
- FSTL4 | c.2062G>A p.V688I | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as rs749842205, COSV99531572; called by muse, mutect2, varscan2
- FTMT | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV58421472, COSV58421974; called by muse, mutect2, varscan2
- FUBP1 | c.1832A>G p.Y611C | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99627939; called by muse, mutect2, varscan2
- GABPB1 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV99589598; called by muse, mutect2, varscan2
- GABRA2 | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100733889; called by muse, mutect2, varscan2
- GABRA6 | c.682G>T p.V228F | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99194101, COSV99194103; called by muse, mutect2, varscan2
- GABRB2 | c.1382C>G p.A461G (on ENST00000274547; = p.A423G on NM_000813.3) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.258); catalogued as COSV50949024, COSV99195691; called by muse, mutect2, varscan2
- GABRB3 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs765803669, COSV54665082; called by muse, mutect2, varscan2
- GABRQ | c.1448G>T p.R483L | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.04); catalogued as COSV100941109, COSV104427406; called by muse, mutect2, varscan2
- GAREM1 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV99330293; called by muse, mutect2, varscan2
- GAS2L3 | c.601A>G p.I201V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs759989294, COSV99902707; called by mutect2, varscan2
- GAS2L3 | c.860C>T p.T287I | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs773862403, COSV99902709; called by muse, mutect2, varscan2
- GDNF | c.46A>T p.T16S | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV100427356; called by muse, mutect2, varscan2
- GHR | c.1703C>A p.T568N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV100049978; called by muse, mutect2, varscan2
- GLUD2 | c.456C>A p.Y152* | Nonsense Mutation (SNP) | VAF 26/95 reads (27%) | catalogued as COSV100046635; called by muse, mutect2, varscan2
- GNB2 | c.803A>T p.N268I | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs147810006; called by muse, mutect2, varscan2
- GPANK1 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs1240733013, COSV100788972; called by muse, mutect2, varscan2
- GPHN | c.2092A>T p.S698C (on ENST00000315266 / NM_001377519.1; = p.S731C on NM_020806.5) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV59479838; called by muse, mutect2, varscan2
- GPR50 | c.1015C>A p.R339S | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as rs765982317, COSV54438725, COSV54439468; called by muse, mutect2, varscan2
- GRIA1 | c.1646G>T p.G549V | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99598431; called by muse, mutect2, varscan2
- GRXCR1 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV101295628; called by muse, mutect2, varscan2
- GSE1 | c.1570G>C p.E524Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as COSV99495871; called by muse, varscan2
- GTF2A1 | c.1037A>T p.K346I | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1299371432, COSV99993324; called by muse, mutect2, varscan2
- GUCD1 | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV101238102; called by muse, mutect2, varscan2
- HADH | c.710-1G>A p.X237_splice | Splice Site (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100531198; called by muse, mutect2, varscan2
- HAPLN1 | c.407G>T p.R136I | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV57148797; called by muse, mutect2, varscan2
- HCN1 | c.349C>G p.Q117E | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV100298867; called by muse, mutect2, varscan2
- HDAC2 | c.1256A>T p.E419V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV100892554; called by muse, mutect2, varscan2
- HECTD2 | c.419A>T p.E140V | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.878); catalogued as COSV99978213; called by muse, mutect2, varscan2
- HHIP | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV56840042, COSV99666714; called by muse, mutect2, varscan2
- HNRNPDL | c.1259A>G p.Y420C | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99787010; called by muse, mutect2, varscan2
- HOXD3 | c.523A>T p.N175Y | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV99979920; called by muse, mutect2, varscan2
- HSPB3 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100115880; called by muse, mutect2, varscan2
- HTR1A | c.679C>G p.R227G | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100108950, COSV60499859; called by muse, mutect2, varscan2
- HTR1D | c.932T>A p.I311N | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100024715; called by muse, mutect2, varscan2
- HTR7 | c.1170C>G p.D390E | Missense Mutation (SNP) | VAF 56/255 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV99519069; called by muse, mutect2, varscan2
- HYDIN | c.12027C>A p.Y4009* | Nonsense Mutation (SNP) | VAF 23/111 reads (21%) | catalogued as COSV101124918; called by muse, mutect2, varscan2
- ICAM1 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99320535; called by muse, mutect2
- IGKV4-1 | c.309C>A p.S103R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.674); catalogued as rs372416266; called by muse, mutect2, varscan2
- IGSF10 | c.2412G>T p.E804D | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV99176792; called by muse, mutect2, varscan2
- IGSF9B | c.3931G>A p.G1311R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.169); catalogued as COSV100317107; called by muse, mutect2, varscan2
- IL13RA1 | c.841A>G p.K281E | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.104); catalogued as COSV100861517; called by muse, mutect2, varscan2
- IL7R | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.036); catalogued as COSV100285960; called by muse, mutect2, varscan2
- IMPG1 | c.1962C>A p.H654Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV100886126, COSV64059477; called by muse, mutect2, varscan2
- IMPG2 | c.3334C>T p.L1112F | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99514915; called by muse, mutect2, varscan2
- INPP4B | c.1562G>A p.W521* | Nonsense Mutation (SNP) | VAF 15/88 reads (17%) | catalogued as COSV99523211; called by muse, mutect2, varscan2
- INTS1 | c.2788G>C p.E930Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV101247514; called by muse, mutect2, varscan2
- IPO8 | c.2182G>T p.G728* | Nonsense Mutation (SNP) | VAF 18/69 reads (26%) | catalogued as COSV99804813; called by muse, mutect2, varscan2
- IQGAP3 | c.2108C>G p.S703C | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.498); catalogued as COSV100752080, COSV63253373; called by muse, mutect2, varscan2
- IQSEC1 | c.1667C>T p.P556L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1362238013, COSV99831405; called by muse, mutect2, varscan2
- IRF2 | c.425A>T p.E142V | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV101165777; called by muse, mutect2, varscan2
- ITGBL1 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101095108; called by muse, varscan2
- ITIH6 | c.755T>A p.V252E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV99512911; called by muse, mutect2, varscan2
- IVD | c.1222G>T p.G408W (on ENST00000651168; = p.G405W on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99991387; called by muse, mutect2, varscan2
- JAKMIP3 | c.2316G>C p.K772N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV100058726; called by muse, mutect2, varscan2
- JAZF1 | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.828); catalogued as COSV99386124; called by muse, mutect2, varscan2
- JPH4 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV100689070; called by muse, mutect2, varscan2
- JUND | c.801G>T p.E267D | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV99417150; called by muse, mutect2, varscan2
- KALRN | c.4002A>T p.Q1334H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99562443; called by mutect2, varscan2
- KARS1 | c.1022A>T p.Y341F | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100093798; called by muse, mutect2, varscan2
- KCNA1 | c.544G>C p.V182L | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as COSV101230141, COSV66838528; called by muse, mutect2, varscan2
- KCNH7 | c.3073G>C p.D1025H | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV59799281, COSV59801343; called by muse, mutect2, varscan2
- KCNIP2 | c.325G>T p.V109F (on ENST00000356640 / NM_173191.3; = p.V124F on NM_014591.5) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99493180; called by muse, mutect2, varscan2
- KCNJ2 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555603894, CM150737, COSV99696226; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNJ3 | c.1030C>A p.Q344K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.267); catalogued as COSV54536138, COSV99715345; called by muse, mutect2, varscan2
- KCNN2 | c.1009G>T p.D337Y (on ENST00000264773; = p.D549Y on NM_021614.4) | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV99298883; called by muse, mutect2, varscan2
- KDM4A | c.461G>T p.R154I | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100969388; called by muse, mutect2, varscan2
- KIAA0100 | c.6068A>G p.H2023R | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.388); catalogued as COSV99971953; called by muse, mutect2, varscan2
- KIAA1210 | c.4838C>G p.P1613R | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV101273941; called by muse, mutect2, varscan2
- KIFAP3 | c.966A>T p.L322F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100810949; called by muse, mutect2, varscan2
- KIFC1 | c.1837G>T p.V613L | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV100995992; called by muse, mutect2, varscan2
- KNDC1 | c.5112G>T p.Q1704H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV100463534; called by muse, mutect2, varscan2
- KPNA1 | c.1514G>A p.G505E | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.619); catalogued as COSV100724117; called by muse, mutect2, varscan2
- KRCC1 | c.137A>G p.Y46C | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100712801; called by muse, mutect2, varscan2
- KRT75 | c.860T>C p.V287A | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV99359211; called by muse, mutect2, varscan2
- KRTAP13-2 | c.243C>A p.Y81* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as COSV101299623, COSV67761924; called by muse, mutect2, varscan2
- KRTAP13-3 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100481715; called by muse, mutect2, varscan2
- KRTAP9-3 | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.16); catalogued as COSV101370120; called by muse, mutect2, varscan2
- L1CAM | c.1330G>T p.A444S | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as CD972291, COSV100648893; called by muse, mutect2, varscan2
- LAMB4 | c.4227C>A p.H1409Q | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.061); catalogued as COSV99222735, COSV99223027; called by muse, mutect2, varscan2
- LENG8 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100417876, COSV58726624, COSV58727305; called by muse, mutect2, varscan2
- LONRF3 | c.1402G>T p.A468S (on ENST00000371628 / NM_001031855.3; = p.A427S on NM_024778.5) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100504244, COSV59151681; called by muse, mutect2, varscan2
- LRP1B | c.13519G>T p.G4507* | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as COSV101253504; called by muse, mutect2, varscan2
- LRRC10 | c.366C>A p.N122K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100825445; called by muse, mutect2, varscan2
- LRRC30 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101274377; called by muse, mutect2, varscan2
- LRRC46 | c.764C>A p.A255E | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780391278, COSV99273963, COSV99274282; called by muse, mutect2, varscan2
- LRRK2 | c.571+1G>T p.X191_splice | Splice Site (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100109398, COSV54172294; called by muse, mutect2, varscan2
- MAD2L1 | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV99633714; called by muse, mutect2, varscan2
- MAGEC2 | c.522C>A p.Y174* | Nonsense Mutation (SNP) | VAF 46/210 reads (22%) | catalogued as COSV55998029; called by muse, mutect2, varscan2
- MAGI2 | c.1510C>A p.L504M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV100833253, COSV62669186; called by muse, mutect2, varscan2
- MAP3K6 | c.2322G>T p.G774= | Splice Region (SNP) | VAF 8/52 reads (15%) | catalogued as rs1040402172, COSV100709061; called by muse, mutect2
- MATR3 | c.1718A>T p.K573I | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100735113; called by muse, mutect2, varscan2
- MCCD1 | c.290T>C p.L97P | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1388680309, COSV100871033; called by muse, mutect2
- MEF2B | c.712A>G p.T238A | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99364373; called by muse, mutect2, varscan2
- MEF2C | c.287G>T p.C96F | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV100424707; called by muse, mutect2, varscan2
- METTL17 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100068476; called by muse, mutect2, varscan2
- MGA | c.6308A>C p.K2103T (on ENST00000219905 / NM_001164273.1; = p.K1894T on NM_001080541.2) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.024); catalogued as rs1240687495, COSV99578749; called by muse, mutect2, varscan2
- MICALL2 | c.2023G>A p.V675I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs142157538, COSV52519859; called by muse, mutect2, varscan2
- MINDY3 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.694); catalogued as COSV99510510; called by muse, mutect2
- MINPP1 | c.1363T>A p.Y455N | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100916743; called by muse, mutect2, varscan2
- MKRN3 | c.152C>A p.A51E | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100090824, COSV58812095; called by muse, mutect2, varscan2
- MKRN3 | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.355); catalogued as COSV100090827; called by muse, mutect2, varscan2
- MOBP | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | PolyPhen probably damaging (0.977); catalogued as COSV60654585; called by muse, mutect2, varscan2
- MROH2B | c.2687G>T p.W896L | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101270541; called by muse, mutect2
- MRPL15 | c.250A>T p.N84Y | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.04); catalogued as COSV99477507; called by muse, mutect2, varscan2
- MS4A14 | c.758C>G p.P253R | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV100280094; called by muse, mutect2, varscan2
- MTMR11 | c.467A>C p.Q156P (on ENST00000439741 / NM_001145862.2; = p.Q84P on NM_181873.3) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as rs1553768692, COSV100808766; called by muse, mutect2, varscan2
- MTMR8 | c.2055G>C p.L685F | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100878321; called by muse, mutect2, varscan2
- MUC3A | c.8818C>A p.R2940S | Missense Mutation (SNP) | VAF 59/465 reads (13%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV100114046; called by muse, mutect2, varscan2
- MYH2 | c.5806A>G p.K1936E | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.044); catalogued as COSV99819382; called by muse, mutect2, varscan2
- MYO1B | c.1463A>G p.H488R | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV100268637; called by muse, mutect2, varscan2
- MYOM2 | c.2887G>T p.D963Y | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV100036797; called by muse, mutect2, varscan2
- N4BP1 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV52210377, COSV99284804; called by muse, mutect2, varscan2
- NAA16 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs765048221, COSV101038250; called by muse, mutect2, varscan2
- NALCN | c.622G>C p.V208L | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99213303; called by muse, mutect2, varscan2
- NAV2 | c.4084G>T p.D1362Y (on ENST00000396087 / NM_001244963.2; = p.D1339Y on NM_145117.5) | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100216274; called by muse, mutect2, varscan2
- NAV3 | c.2494A>G p.R832G | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as rs750808809, COSV99887496; called by muse, mutect2, varscan2
- NCKAP1L | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV99514560; called by muse, mutect2, varscan2
- NDNF | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as COSV101113095; called by muse, mutect2, varscan2
- NDUFB8 | c.388T>G p.C130G | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.95); catalogued as COSV100144030; called by muse, mutect2, varscan2
- NEDD4 | c.1953G>C p.E651D (on ENST00000508342 / NM_001284338.1; = p.E232D on NM_006154.4) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100163382, COSV59063337; called by muse, mutect2, varscan2
- NEO1 | c.3484G>C p.D1162H | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767605567, COSV56070916; called by muse, mutect2, varscan2
- NLRC4 | c.2096G>T p.G699V | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV100707244; called by muse, mutect2, varscan2
- NLRP2 | c.2447T>C p.V816A | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV99671955; called by muse, mutect2, varscan2
- NLRP3 | c.2924G>T p.G975V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.258); catalogued as COSV100275354; called by muse, mutect2
- NLRP8 | c.638G>C p.G213A | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99404808, COSV99405952; called by muse, mutect2, varscan2
- NME8 | c.454+1G>T p.X152_splice | Splice Site (SNP) | VAF 14/55 reads (25%) | catalogued as COSV99552875; called by muse, mutect2, varscan2
- NOD2 | c.2240A>T p.Y747F | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.397); catalogued as COSV100318258; called by muse, mutect2, varscan2
- NOTCH1 | c.5539C>T p.H1847Y | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV53073284; called by muse, mutect2, varscan2
- NOX3 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT tolerated (0.95); PolyPhen probably damaging (1); catalogued as COSV99342778; called by muse, mutect2, varscan2
- NPAP1 | c.340G>C p.V114L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV100274854, COSV61507542; called by muse, mutect2, varscan2
- NPAP1 | c.2611G>T p.V871F | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.354); catalogued as COSV100274856; called by muse, mutect2, varscan2
- NR2E1 | c.52G>T p.V18L | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934362; called by muse, mutect2, varscan2
- NR5A2 | c.1436C>T p.A479V (on ENST00000367362 / NM_205860.3; = p.A433V on NM_003822.5) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as rs752897392, COSV99370731; called by muse, varscan2
- NRDC | c.46A>C p.K16Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.18); catalogued as COSV100703138; called by muse, mutect2, varscan2
- NRG3 | c.304C>A p.L102I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV100930814; called by muse, mutect2, varscan2
- NSDHL | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100938609; called by muse, mutect2, varscan2
- NUTM1 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as rs535995310, COSV100412120; called by muse, mutect2, varscan2
- NWD1 | c.832C>T p.L278F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100341844; called by muse, mutect2, varscan2
- OLFML2B | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1397019717, COSV54198735; called by muse, mutect2, varscan2
- ONECUT1 | c.722T>C p.M241T | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.775); catalogued as COSV100009054; called by muse, mutect2, varscan2
- OR10C1 | c.478del p.H160Tfs*87 (on ENST00000622521; = p.H158Tfs*87 on NM_013941.3) | Frame Shift Del (DEL) | VAF 22/133 reads (17%) | catalogued as COSV65822996; called by mutect2, pindel, varscan2
- OR10J1 | c.748C>T p.H250Y | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV101419800, COSV101420010; called by muse, mutect2, varscan2
- OR11A1 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV101010681, COSV101010702; called by muse, mutect2, varscan2
- OR14C36 | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV100507398; called by muse, mutect2, varscan2
- OR14K1 | c.236C>A p.S79Y | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); catalogued as COSV51720294, COSV99314976, COSV99315195; called by muse, mutect2, varscan2
- OR1A1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV100410727; called by muse, mutect2, varscan2
- OR2B6 | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); catalogued as COSV99773636; called by muse, mutect2, varscan2
- OR2L13 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63549238; called by muse, mutect2, varscan2
- OR2L8 | c.722G>T p.S241I | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100594052; called by muse, mutect2, varscan2
- OR2T4 | c.303G>T p.M101I | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs780158745, COSV100822402, COSV63543440; called by muse, mutect2
- OR4K13 | c.167A>G p.H56R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100237648; called by muse, mutect2, varscan2
- OR4K14 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.044); catalogued as rs374172388, COSV59292293; called by muse, mutect2, varscan2
- OR4K5 | c.353T>A p.M118K | Missense Mutation (SNP) | VAF 100/670 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV100262174; called by muse, mutect2, varscan2
- OR51B6 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs748892217, COSV100970750; called by muse, mutect2, varscan2
- OR52B2 | c.633G>T p.L211F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as COSV101603926; called by muse, mutect2, varscan2
- OR5D13 | c.591C>A p.S197R | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100686745, COSV62334561; called by muse, mutect2, varscan2
- OR5J2 | c.88G>T p.V30L | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100398917, COSV56622088; called by muse, mutect2, varscan2
- OR5M8 | c.914C>G p.S305* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100510563; called by muse, mutect2
- OR5V1 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.996); catalogued as COSV101011130; called by muse, mutect2, varscan2
- OR8U1 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100163780; called by muse, varscan2
- OR9G1 | c.20C>A p.T7K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV100380258; called by muse, mutect2, varscan2
- OR9Q1 | c.898C>A p.L300M | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV100109449; called by muse, mutect2, varscan2
- ORM2 | c.221C>G p.T74R | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV99407444; called by muse, mutect2, varscan2
- OVGP1 | c.65A>G p.H22R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV100868019; called by muse, mutect2, varscan2
- PAAF1 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100142339, COSV60154756; called by muse, mutect2, varscan2
- PAPPA2 | c.2558T>C p.I853T | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV100866579; called by muse, mutect2, varscan2
- PAPPA2 | c.3234C>A p.D1078E | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs748710026, COSV100867626; called by muse, mutect2, varscan2
- PBX4 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs761605001, COSV52064639; called by muse, mutect2, varscan2
- PC | c.1312A>G p.T438A | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV100540705; called by muse, mutect2, varscan2
- PCDH11X | c.102G>T p.M34I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.229); catalogued as rs2524441, COSV100008880, COSV53510058; called by muse, mutect2
- PCDH8 | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.035); catalogued as COSV100131263; called by muse, mutect2, varscan2
- PCDHAC2 | c.1186C>A p.P396T | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV99144535; called by muse, mutect2, varscan2
- PCDHB1 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100128040; called by muse, mutect2, varscan2
- PCDHB10 | c.186G>T p.R62S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); catalogued as COSV99503761; called by muse, mutect2, varscan2
- PCDHB13 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as rs782100128, COSV99506822; called by muse, mutect2, varscan2
- PCDHB3 | c.902T>A p.M301K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.15); catalogued as COSV99164253; called by muse, mutect2, varscan2
- PCDHB4 | c.1897G>T p.D633Y | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99521905; called by muse, mutect2, varscan2
- PCDHGA11 | c.1846G>C p.G616R | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as COSV99532219; called by muse, mutect2, varscan2
- PCDHGB3 | c.1426G>T p.A476S | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99532215; called by muse, mutect2, varscan2
- PCDHGB4 | c.1528G>A p.G510R | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53965507; called by muse, mutect2, varscan2
- PCSK5 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV100949593; called by muse, mutect2, varscan2
- PDE8B | c.1319C>A p.S440Y | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53738286, COSV99366239; called by muse, mutect2, varscan2
- PDZD8 | c.2379C>A p.F793L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53694203; called by muse, mutect2, varscan2
- PDZRN4 | c.2539G>C p.A847P (on ENST00000402685 / NM_001164595.2; = p.A589P on NM_013377.4) | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV100113766, COSV54192255; called by muse, mutect2, varscan2
- PEX5L | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99828024; called by muse, mutect2, varscan2
- PGM5 | c.1598A>T p.H533L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.058); catalogued as COSV101123842; called by muse, mutect2, varscan2
- PHF14 | c.1360G>T p.V454F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101301774; called by muse, mutect2, varscan2
- PIK3CG | c.986G>T p.C329F | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs1395210099, COSV100782595; called by muse, mutect2, varscan2
- PLCH1 | c.2339G>C p.R780P (on ENST00000340059 / NM_001130960.2; = p.R792P on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100395773; called by muse, mutect2, varscan2
- PLCXD3 | c.857G>C p.G286A | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100125309; called by muse, mutect2, varscan2
- PLXNA1 | c.5476A>G p.I1826V | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV52531648; called by muse, mutect2, varscan2
- PLXNC1 | c.1769C>A p.T590N | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.601); catalogued as COSV99312540; called by muse, mutect2, varscan2
- POLR2B | c.2116G>C p.V706L | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV100107883; called by muse, mutect2, varscan2
- POU3F3 | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63722453; called by muse, mutect2, varscan2
- PPFIA2 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs779142085, COSV100331902, COSV61043239; called by muse, mutect2, varscan2
- PPP1R17 | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100566297; called by muse, mutect2, varscan2
- PPP1R9A | c.880G>T p.G294C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV99194691; called by muse, varscan2
- PPP2R2B | c.743G>T p.R248L (on ENST00000394409; = p.R314L on NM_181674.2) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV100353606; called by muse, mutect2, varscan2
- PPP4R1 | c.2601G>T p.M867I (on ENST00000400556 / NM_001042388.3; = p.M850I on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV99553201; called by muse, mutect2, varscan2
- PPP6R1 | c.1490A>T p.E497V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV69800932; called by muse, mutect2, varscan2
- PPP6R3 | c.1396A>G p.N466D (on ENST00000393800 / NM_001352375.2; = p.N415D on NM_018312.5) | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99675738; called by muse, mutect2, varscan2
- PREPL | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.733); catalogued as COSV53218294, COSV99575956; called by muse, mutect2, varscan2
- PRKAA2 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV100982759; called by muse, mutect2, varscan2
- PRKD1 | c.1167C>A p.H389Q | Missense Mutation (SNP) | VAF 54/335 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100119424, COSV59563940; called by muse, mutect2, varscan2
- PRPF3 | c.1690G>T p.A564S | Missense Mutation (SNP) | VAF 63/332 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV100254553; called by muse, mutect2, varscan2
- PRR30 | c.332C>G p.S111C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV53205307, COSV99574331; called by muse, mutect2, varscan2
- PSMC2 | c.1089T>A p.S363R | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV99485171; called by muse, mutect2, varscan2
- PTGER3 | c.1139G>T p.R380M | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100656080; called by muse, mutect2, varscan2
- PTGER3 | c.1170A>T p.R390S | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100138373; called by muse, mutect2, varscan2
- PTH2R | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV55921259, COSV99782140; called by muse, mutect2
- PTH2R | c.1467C>A p.H489Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV99782141; called by muse, mutect2, varscan2
- PTPN7 | c.244del p.T83Pfs*20 (on ENST00000495688; = p.T122Pfs*20 on NM_002832.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as COSV100459826; called by pindel, varscan2*
- PTPRC | c.3689C>A p.P1230H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100722172; called by muse, mutect2, varscan2
- PTPRT | c.4039C>T p.P1347S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV100625567, COSV61984036; called by muse, mutect2
- RAB3GAP1 | c.233A>G p.Y78C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.293); catalogued as rs1009214570, COSV99920694; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2460G>T p.W820C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100741056; called by muse, mutect2, varscan2
- RAB3IP | c.49A>G p.M17V (on ENST00000550536 / NM_175623.4; = p.M1? on NM_022456.5) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as rs1565875916, COSV99922970; called by muse, mutect2, varscan2
- RAB3IP | c.488G>T p.S163I (on ENST00000550536 / NM_175623.4; = p.S147I on NM_022456.5) | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99922972; called by muse, mutect2, varscan2
- RABGGTB | c.14A>G p.Q5R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs770958961, COSV100174937; called by muse, mutect2, varscan2
- RAD17 | c.1841G>T p.G614V (on ENST00000380774 / NM_133339.2; = p.G603V on NM_002873.1) | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV99281194; called by muse, mutect2, varscan2
- RAN | c.248-1G>A p.X83_splice | Splice Site (SNP) | VAF 11/41 reads (27%) | catalogued as COSV54562694; called by muse, mutect2, varscan2
- RASD2 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.109); catalogued as rs1309164572, COSV99332675; called by muse, mutect2, varscan2
- RBPJ | c.253dup p.E85Gfs*10 | Frame Shift Ins (INS) | VAF 26/139 reads (19%) | catalogued as COSV60748872; called by mutect2, pindel, varscan2
- RFWD3 | c.974G>T p.R325L | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.43); catalogued as COSV100736181; called by muse, mutect2, varscan2
- RIBC2 | c.432G>T p.Q144H | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV100663007; called by muse, mutect2, varscan2
- RIMS2 | c.2345G>T p.R782I (on ENST00000666250 / NM_001348490.2; = p.R590I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1396119669, COSV51663724, COSV51724154; called by muse, mutect2
- RNF112 | c.495G>T p.R165S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV101518335; called by muse, mutect2, varscan2
- RPF1 | c.285G>A p.K95= | Splice Region (SNP) | VAF 22/80 reads (28%) | catalogued as COSV101039696; called by muse, mutect2, varscan2
- RPP40 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1259248166, COSV100123903; called by muse, mutect2, varscan2
- RPS6KC1 | c.1228G>T p.G410C | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100873784, COSV65297070; called by muse, mutect2, varscan2
- RPS6KL1 | c.1411G>T p.G471W | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100664994; called by muse, mutect2, varscan2
- RSPH14 | c.709G>T p.V237F | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99320484; called by muse, mutect2, varscan2
- RTN1 | c.491C>A p.S164Y | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99954783; called by muse, mutect2, varscan2
- SAAL1 | c.1240-1G>C p.X414_splice | Splice Site (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100253757; called by muse, mutect2, varscan2
- SALL1 | c.405C>A p.S135R | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV51765337, COSV99171628; called by muse, mutect2, varscan2
- SAMD9 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101180137; called by muse, mutect2, varscan2
- SBSN | c.58T>A p.S20T | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101510041; called by muse, mutect2, varscan2
- SCAP | c.225A>T p.Q75H | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.109); catalogued as COSV99652480; called by muse, mutect2, varscan2
- SCN10A | c.1736C>G p.P579R | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV101479265; called by muse, mutect2, varscan2
- SCTR | c.1060C>G p.H354D | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99191520; called by muse, mutect2, varscan2
- SCUBE3 | c.1615G>T p.A539S | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.192); catalogued as COSV99234018; called by muse, mutect2, varscan2
- SEC11C | c.541G>C p.V181L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV100230953; called by muse, mutect2, varscan2
- SEMA6B | c.1525G>A p.G509S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0.013); catalogued as rs1298993659, COSV100014666; called by muse, mutect2, varscan2
- SESN1 | c.428A>T p.H143L (on ENST00000356644 / NM_001199933.1; = p.H202L on NM_014454.3) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.185); catalogued as rs374094607, COSV100122700; called by muse, mutect2, varscan2
- SESTD1 | c.752T>A p.L251* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as COSV100090235; called by muse, mutect2, varscan2
- SETD1A | c.3520G>T p.E1174* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as COSV99352510; called by muse, mutect2, varscan2
- SETD1A | c.4223C>T p.P1408L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs377102722; called by muse, varscan2
- SH3KBP1 | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as COSV101114419; called by muse, mutect2, varscan2
- SH3PXD2A | c.3029G>A p.R1010Q (on ENST00000369774 / NM_001365079.1; = p.R982Q on NM_014631.2) | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as rs576268163, COSV100279892; called by muse, mutect2, varscan2
- SHROOM4 | c.3605C>A p.P1202Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV99173046; called by muse, mutect2, varscan2
- SIM2 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV51768328; called by muse, mutect2
- SLC22A14 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756231072, COSV56197608; called by muse, mutect2, varscan2
- SLC34A3 | c.1418T>A p.L473Q | Missense Mutation (SNP) | VAF 81/134 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV100746623; called by muse, mutect2, varscan2
- SLC39A4 | c.1063G>T p.G355W (on ENST00000301305 / NM_001374839.1; = p.G330W on NM_017767.3) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as COSV99433038; called by muse, mutect2, varscan2
- SLC4A4 | c.2124G>T p.M708I (on ENST00000264485 / NM_001098484.3; = p.M664I on NM_003759.4) | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.058); catalogued as COSV99139056; called by muse, mutect2, varscan2
- SLC4A9 | c.764C>G p.S255C (on ENST00000507527 / NM_001258428.2; = p.S231C on NM_031467.3) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV99138457; called by muse, mutect2
- SLC6A16 | c.574-1G>T p.X192_splice | Splice Site (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100242588; called by muse, mutect2, varscan2
- SLC7A3 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1217645907, COSV99979367; called by muse, mutect2, varscan2
- SLCO1A2 | c.269G>C p.G90A | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.441); catalogued as COSV100261379; called by muse, mutect2, varscan2
- SLITRK2 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.231); catalogued as COSV100157387; called by muse, mutect2, varscan2
- SLITRK4 | c.1923T>G p.F641L | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.084); catalogued as COSV100567180; called by muse, varscan2
- SLITRK4 | c.1870A>T p.I624F | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV100567182; called by muse, varscan2
- SLITRK4 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62024000, COSV62025364; called by muse, mutect2, varscan2
- SMG8 | c.2965G>T p.V989L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.009); catalogued as COSV99958700; called by muse, mutect2, varscan2
- SORCS1 | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs747517715, COSV99543849; called by muse, mutect2, varscan2
- SPAG17 | c.4147G>T p.V1383L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV100308165; called by muse, mutect2, varscan2
- SPAG17 | c.1107G>T p.M369I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV100308166; called by muse, mutect2, varscan2
- SPAG6 | c.1006-1G>A p.X336_splice | Splice Site (SNP) | VAF 6/39 reads (15%) | catalogued as rs1416895451, COSV100509985, COSV100510449; called by muse, mutect2
- SPANXN1 | c.218G>T p.*73Lext*? | Nonstop Mutation (SNP) | VAF 19/133 reads (14%) | catalogued as COSV100979299; called by muse, mutect2, varscan2
- SPHKAP | c.4290G>C p.Q1430H | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.132); catalogued as COSV100763760, COSV100764074; called by muse, mutect2, varscan2
- SPHKAP | c.3905C>A p.T1302N | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100763761; called by muse, mutect2, varscan2
- SPRY3 | c.806T>A p.V269E | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100249209; called by muse, mutect2, varscan2
- SRPK1 | c.1267G>C p.D423H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.428); catalogued as COSV100644284; called by muse, mutect2, varscan2
- ST8SIA1 | c.345C>A p.F115L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99682809; called by muse, mutect2, varscan2
- STXBP5L | c.1029G>T p.M343I | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as rs555306958, COSV99872357; called by muse, mutect2, varscan2
- SUCLG1 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101205360; called by muse, mutect2, varscan2
- SULT1C3 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV100227344; called by muse, mutect2, varscan2
- SUSD5 | c.1292T>G p.M431R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100534946, COSV100534948; called by muse, mutect2, varscan2
- TAAR9 | c.708C>G p.S236R | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV101453306; called by muse, mutect2, varscan2
- TAL1 | c.923C>A p.P308H | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV53748343, COSV53749124; called by muse, mutect2, varscan2
- TASOR2 | c.151C>A p.Q51K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV100050036; called by muse, mutect2, varscan2
- TBC1D2B | c.2003G>T p.R668L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100316900, COSV56043345; called by muse, mutect2, varscan2
- TBCCD1 | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100111828, COSV58661978; called by muse, mutect2, varscan2
- TCERG1 | c.2668G>C p.E890Q | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99694467; called by muse, mutect2, varscan2
- TCF20 | c.2380C>G p.Q794E | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as rs1179947634, COSV100166322; called by muse, mutect2, varscan2
- TDRD1 | c.3073G>C p.A1025P | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99314155; called by muse, mutect2, varscan2
- TEKT5 | c.396G>C p.Q132H | Missense Mutation (SNP) | VAF 63/260 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV99295868; called by muse, mutect2, varscan2
- TENM1 | c.4912G>T p.G1638W | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100949229; called by muse, mutect2, varscan2
- TENM1 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.247); catalogued as COSV100949230, COSV64445875; called by muse, mutect2, varscan2
- TENT5C | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV65616038, COSV65617398; called by muse, mutect2
- TEX37 | c.287G>T p.R96M | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.025); catalogued as COSV100304578; called by muse, mutect2, varscan2
- TEX55 | c.646A>T p.K216* | Nonsense Mutation (SNP) | VAF 26/119 reads (22%) | catalogued as COSV99817335; called by muse, mutect2, varscan2
- TFPT | c.614C>G p.A205G | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.066); catalogued as rs545448952, COSV100338121, COSV57837379; called by muse, mutect2, varscan2
- TG | c.8243G>C p.G2748A | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.033); catalogued as COSV99599376, COSV99600076; called by muse, mutect2, varscan2
- TLL1 | c.1981G>T p.E661* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as COSV99285975, COSV99286385; called by muse, mutect2, varscan2
- TLL2 | c.1248G>T p.W416C | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100780154; called by muse, mutect2, varscan2
- TLN2 | c.5725G>T p.E1909* | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | catalogued as COSV100168195; called by muse, mutect2, varscan2
- TMC3 | c.2809C>G p.P937A | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); catalogued as COSV100845849; called by muse, mutect2, varscan2
- TMEM132D | c.1421C>G p.S474W | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101396633, COSV101399631, COSV70602045; called by muse, mutect2, varscan2
- TMEM159 | c.468G>C p.E156D | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.172); catalogued as COSV99238545; called by muse, mutect2, varscan2
- TMEM200A | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99758744; called by muse, mutect2, varscan2
- TMEM65 | c.541G>C p.A181P | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99899074; called by muse, mutect2, varscan2
- TMTC1 | c.2042A>T p.H681L (on ENST00000539277 / NM_001193451.2; = p.H573L on NM_175861.3) | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99758892; called by muse, mutect2, varscan2
- TNFRSF10A | c.1140G>A p.W380* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as COSV99646074; called by muse, mutect2, varscan2
- TNIK | c.1575G>C p.M525I | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV52695442; called by muse, mutect2
- TNNT3 | c.756-2A>G p.X252_splice (on ENST00000397301 / NM_001367846.1; = p.X241_splice on NM_006757.4) | Splice Site (SNP) | VAF 16/72 reads (22%) | catalogued as COSV99547960; called by muse, mutect2, varscan2
- TNXB | c.7985G>T p.G2662V (on ENST00000647633; = p.G2415V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99056710; called by muse, mutect2, varscan2
- TOPBP1 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV99604979; called by muse, mutect2, varscan2
- TOX2 | c.329C>T p.P110L (on ENST00000358131 / NM_001098798.2; = p.P59L on NM_032883.3) | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); catalogued as COSV100363410; called by muse, mutect2, varscan2
- TRAM1L1 | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100162022; called by muse, mutect2, varscan2
- TRIM37 | c.376G>C p.G126R | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV99232386; called by muse, mutect2, varscan2
- TRIM42 | c.1129A>G p.R377G | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99648036; called by muse, mutect2, varscan2
- TRIM48 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.755); catalogued as COSV101338203; called by muse, mutect2, varscan2
- TRIM58 | c.106T>A p.C36S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100824915; called by muse, mutect2
- TRPC4 | c.2921C>A p.T974N (on ENST00000379705 / NM_016179.4; = p.T979N on NM_003306.3) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.245); catalogued as COSV100156035; called by muse, mutect2, varscan2
- TTN | c.74926A>G p.K24976E (on ENST00000591111; = p.K17552E on NM_003319.4) | Missense Mutation (SNP) | VAF 39/162 reads (24%) | PolyPhen possibly damaging (0.453); catalogued as COSV100597234; called by muse, mutect2, varscan2
- TTN | c.68998G>A p.E23000K (on ENST00000591111; = p.E15576K on NM_003319.4) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | PolyPhen benign (0.209); catalogued as rs993198870, COSV100597238, COSV60189867; called by muse, mutect2, varscan2
- TTN | c.63706A>T p.I21236L (on ENST00000591111; = p.I13812L on NM_003319.4) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | PolyPhen benign (0.001); catalogued as COSV100597239; called by muse, mutect2, varscan2
- TTN | c.63467C>G p.P21156R (on ENST00000591111; = p.P13732R on NM_003319.4) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | PolyPhen probably damaging (0.938); catalogued as COSV100597244, COSV59869160; called by muse, mutect2, varscan2
- TTN | c.35885C>A p.P11962H (on ENST00000591111; = p.P4538H on NM_003319.4) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | PolyPhen possibly damaging (0.694); catalogued as COSV100597249; called by muse, mutect2, varscan2
- TTN | c.18658T>A p.S6220T (on ENST00000591111; = p.S5293T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | PolyPhen benign (0.021); catalogued as COSV100597250; called by muse, mutect2, varscan2
- TTN | c.9439G>T p.V3147F (on ENST00000591111; = p.V3101F on NM_003319.4) | Missense Mutation (SNP) | VAF 20/126 reads (16%) | PolyPhen possibly damaging (0.803); catalogued as COSV100597257; called by muse, mutect2, varscan2
- TYRP1 | c.241C>A p.H81N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV101141205; called by muse, mutect2, varscan2
- UBE2NL | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as rs781819629; called by muse, mutect2, varscan2
- UBIAD1 | c.13C>G p.Q5E | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV100954804; called by muse, mutect2, varscan2
- UBN1 | c.705G>C p.K235N | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99277533; called by muse, mutect2, varscan2
- UBR1 | c.4727A>C p.N1576T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV99316713; called by muse, mutect2, varscan2
- UGT2B4 | c.950C>A p.S317* | Nonsense Mutation (SNP) | VAF 27/149 reads (18%) | catalogued as COSV100522233; called by muse, mutect2, varscan2
- UNC5CL | c.657T>G p.D219E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as COSV99770607; called by muse, mutect2, varscan2
- UPP1 | c.209G>T p.R70M | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.339); catalogued as COSV100080553, COSV100080596; called by muse, mutect2, varscan2
- UQCRFS1 | c.629G>T p.W210L | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100508031; called by muse, mutect2, varscan2
- USP29 | c.1764T>A p.S588R | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.11); catalogued as COSV99517746; called by muse, mutect2, varscan2
- USP34 | c.1273A>G p.I425V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.558); catalogued as COSV68402650; called by muse, mutect2, varscan2
- VANGL2 | c.113del p.G38Afs*7 | Frame Shift Del (DEL) | VAF 23/92 reads (25%) | catalogued as COSV63605661; called by mutect2, pindel, varscan2
- VN1R4 | c.176G>T p.C59F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV100237333; called by muse, mutect2, varscan2
- VPS13C | c.10351G>A p.G3451S (on ENST00000644861 / NM_020821.3; = p.G3408S on NM_017684.5) | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51124540; called by muse, mutect2, varscan2
- VWC2 | c.713G>T p.R238M | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV100513900; called by muse, mutect2, varscan2
- WDR17 | c.1173A>T p.G391= | Splice Region (SNP) | VAF 11/66 reads (17%) | catalogued as COSV54580481, COSV99706940; called by muse, mutect2, varscan2
- WDR17 | c.3421A>T p.S1141C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV99706948; called by muse, mutect2, varscan2
- WDR54 | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV99269357; called by muse, mutect2
- WDR72 | c.1211C>G p.T404S | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as COSV100854271; called by muse, mutect2, varscan2
- WDR90 | c.2987G>T p.W996L | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99552803; called by muse, mutect2, varscan2
- WTAP | c.607+1G>C p.X203_splice | Splice Site (SNP) | VAF 17/70 reads (24%) | catalogued as COSV100493265; called by muse, mutect2, varscan2
- WWC1 | c.2759G>T p.R920L | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV99514386; called by muse, mutect2, varscan2
- XKR9 | c.185G>T p.W62L | Missense Mutation (SNP) | VAF 32/273 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68773200; called by muse, mutect2, varscan2
- XKR9 | c.186G>T p.W62C | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101281827; called by muse, mutect2, varscan2
- XPR1 | c.194A>T p.E65V | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100851426; called by muse, mutect2, varscan2
- XRN1 | c.675A>T p.R225S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99377338; called by muse, mutect2, varscan2
- YWHAH | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99963737; called by muse, mutect2, varscan2
- ZBTB49 | c.1773G>C p.E591D | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100552371, COSV100552656; called by muse, mutect2, varscan2
- ZC3H4 | c.258G>C p.K86N | Missense Mutation (SNP) | VAF 101/383 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as COSV99451791; called by muse, mutect2, varscan2
- ZFAT | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1411842042, COSV100914277; called by muse, mutect2
- ZFAT | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV100914278; called by muse, mutect2, varscan2
- ZNF12 | c.620A>T p.Y207F (on ENST00000405858 / NM_016265.4; = p.Y169F on NM_006956.3) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100703577; called by muse, mutect2, varscan2
- ZNF157 | c.1442G>T p.R481L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100998418; called by muse, mutect2, varscan2
- ZNF184 | c.1261A>C p.N421H | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as COSV99279407; called by muse, mutect2, varscan2
- ZNF185 | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV100248199; called by muse, mutect2, varscan2
- ZNF384 | c.619A>C p.M207L | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100158222; called by muse, mutect2, varscan2
- ZNF420 | c.1747G>T p.G583* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100421171; called by muse, mutect2, varscan2
- ZNF429 | c.1641C>G p.N547K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV100641813, COSV61915663; called by muse, mutect2, varscan2
- ZNF429 | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.67); catalogued as rs1206568586, COSV100641814; called by muse, mutect2, varscan2
- ZNF454 | c.338G>T p.R113I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100194658; called by muse, mutect2, varscan2
- ZNF479 | c.1010C>A p.S337Y | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.136); catalogued as COSV100482404; called by muse, mutect2, varscan2
- ZNF536 | c.923C>A p.A308E | Missense Mutation (SNP) | VAF 67/226 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100834781, COSV62822031; called by muse, mutect2, varscan2
- ZNF583 | c.1025A>G p.H342R | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99381972; called by muse, mutect2, varscan2
- ZNF585A | c.266G>T p.G89V (on ENST00000292841 / NM_001288800.2; = p.G34V on NM_152655.3) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as COSV99492797; called by muse, mutect2, varscan2
- ZNF623 | c.1541C>A p.S514Y | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV101513490; called by muse, mutect2, varscan2
- ZNF667 | c.1236G>T p.K412N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV99410095; called by muse, mutect2, varscan2
- ZNF701 | c.1065G>T p.K355N (on ENST00000301093; = p.K289N on NM_018260.3) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV99990705; called by muse, mutect2, varscan2
- ZNF701 | c.1066G>T p.A356S (on ENST00000301093; = p.A290S on NM_018260.3) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as rs771589414, COSV56523906, COSV99990707; called by muse, mutect2, varscan2
- ZNF71 | c.55G>T p.G19W | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100045614; called by muse, mutect2, varscan2
- ZNF8 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373818346; called by muse, mutect2, varscan2
- ZNF800 | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56175719, COSV99757681; called by muse, mutect2, varscan2
- ZNF831 | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100925814; called by muse, mutect2, varscan2
- ZNF831 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs1443345757, COSV64042957; called by muse, varscan2
- ZNF831 | c.3505A>G p.S1169G | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100925816; called by muse, mutect2, varscan2
- ADAMTS18 | c.2100dup p.V701Sfs*13 | Frame Shift Ins (INS) | VAF 20/131 reads (15%) | called by mutect2, pindel, varscan2
- CCDC141 | c.2371del p.Q791Sfs*21 | Frame Shift Del (DEL) | VAF 18/111 reads (16%) | called by mutect2, pindel, varscan2
- CD1A | c.528_529del p.H176Qfs*5 | Frame Shift Del (DEL) | VAF 18/101 reads (18%) | called by pindel, varscan2
- CD1C | c.889+1del | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- DDX52 | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- EDN3 | c.79dup p.D27Gfs*17 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- FBXO40 | c.115del p.H39Tfs*22 | Frame Shift Del (DEL) | VAF 14/104 reads (13%) | called by mutect2, pindel, varscan2
- IGHV1-2 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- IGHV1-58 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 184/399 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- IGLC7 | c.178A>T p.K60* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- IPO8 | c.832del p.S278Afs*17 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- KMT2D | c.7643_7653del p.K2548Tfs*103 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | called by mutect2, pindel
- LAIR2 | c.104del p.P35Qfs*4 | Frame Shift Del (DEL) | VAF 54/286 reads (19%) | called by mutect2, pindel, varscan2
- NHLRC2 | c.1388del p.G463Vfs*6 | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | called by mutect2, pindel, varscan2
- NPS | c.64dup p.W22Lfs*9 | Frame Shift Ins (INS) | VAF 8/57 reads (14%) | called by mutect2, pindel, varscan2
- P2RY13 | c.251dup p.N84Kfs*20 | Frame Shift Ins (INS) | VAF 43/127 reads (34%) | called by mutect2, pindel, varscan2
- PCDHB10 | c.1838G>T p.G613V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- PCLO | c.10841del p.P3614Lfs*23 | Frame Shift Del (DEL) | VAF 19/108 reads (18%) | called by mutect2, pindel, varscan2
- PLCH1 | c.4934del p.G1645Vfs*47 (on ENST00000340059 / NM_001130960.2; = p.G1637Vfs*47 on NM_014996.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/61 reads (16%) | called by mutect2, pindel, varscan2
- PLEKHG1 | c.475del p.L159Ffs*29 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- PNISR | c.497A>G p.Y166C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2
- PRAMEF10 | c.1202C>A p.T401K | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- PRUNE2 | c.3871del p.E1291Kfs*54 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | called by mutect2, pindel, varscan2
- RASAL2 | c.2579del p.P860Hfs*19 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- SLC25A3 | c.952C>T p.R318C (on ENST00000228318 / NM_005888.3; = p.R317C on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TMEM132D | c.1696del p.R566Afs*15 | Frame Shift Del (DEL) | VAF 29/137 reads (21%) | called by mutect2, pindel, varscan2
- TYW1 | c.526del p.V176Yfs*32 | Frame Shift Del (DEL) | VAF 50/220 reads (23%) | called by mutect2, pindel, varscan2
- UNC13A | c.1209del p.K404Sfs*100 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by mutect2, pindel, varscan2
- XKR3 | c.872C>A p.P291H | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- ZBTB11 | c.1593del p.A533Pfs*14 | Frame Shift Del (DEL) | VAF 14/107 reads (13%) | called by mutect2, pindel, varscan2
- ZMYND12 | c.910dup p.Q304Pfs*40 | Frame Shift Ins (INS) | VAF 49/229 reads (21%) | called by mutect2, pindel, varscan2
- ZNF292 | c.1635_1636del p.L546Vfs*2 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | called by pindel, varscan2
- ZNF831 | c.736del p.L246Ffs*16 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | called by pindel, varscan2
- ACKR1 | c.736C>T p.L246= | Silent (SNP) | VAF 17/141 reads (12%) | catalogued as rs1183720415, COSV100929482; called by muse, mutect2, varscan2
- ACLY | c.1939C>T p.L647= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as COSV100709544; called by muse, mutect2, varscan2
- ADGRB3 | c.3219G>C p.T1073= | Silent (SNP) | VAF 54/215 reads (25%) | catalogued as COSV53238298, COSV99483849; called by muse, mutect2, varscan2
- ADRA2C | c.543C>T p.V181= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV57467676; called by muse, mutect2, varscan2
- AGXT2 | c.444A>G p.E148= | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as rs773145343, COSV99183713; called by muse, mutect2, varscan2
- AHNAK2 | c.2670G>T p.L890= | Silent (SNP) | VAF 194/454 reads (43%) | catalogued as COSV100315926; called by muse, mutect2, varscan2
- AMMECR1 | c.909C>T p.T303= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV99466333; called by muse, mutect2, varscan2
- AMY2A | c.363T>A p.A121= | Silent (SNP) | VAF 31/231 reads (13%) | catalogued as rs1234090654; called by muse, mutect2, varscan2
- ANK1 | c.5244G>A p.Q1748= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV99224159; called by muse, mutect2, varscan2
- ANKAR | c.618A>G p.T206= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs770433805, COSV99853933; called by muse, mutect2, varscan2
- AP002512.3 | c.462C>T p.I154= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs757894426, COSV99687797; called by muse, mutect2, varscan2
- APBA2 | c.420G>A p.E140= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV101381963; called by muse, mutect2, varscan2
- ASXL3 | c.5928T>C p.S1976= | Silent (SNP) | VAF 30/139 reads (22%) | catalogued as COSV99323655; called by muse, mutect2, varscan2
- ATP11C | c.810A>G p.E270= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV100557501; called by muse, mutect2, varscan2
- ATP6V1B1 | c.207C>A p.T69= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV52268396, COSV99313819; called by muse, mutect2
- B3GAT2 | c.904C>A p.R302= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs149616588; called by muse, mutect2, varscan2
- BBS12 | c.198G>T p.V66= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV100044821; called by muse, mutect2, varscan2
- BEST3 | c.1056T>G p.A352= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV100437625; called by muse, mutect2, varscan2
- BHMT | c.1140C>A p.A380= | Silent (SNP) | VAF 41/201 reads (20%) | catalogued as COSV99165376, COSV99165426; called by muse, mutect2, varscan2
- C12orf56 | c.120C>A p.I40= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV100399082; called by muse, mutect2, varscan2
- C9orf152 | c.267G>C p.L89= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV101272371; called by muse, mutect2, varscan2
- CD5L | c.267C>A p.V89= | Silent (SNP) | VAF 53/296 reads (18%) | catalogued as COSV100941006; called by muse, mutect2, varscan2
- CDH19 | c.189C>A p.I63= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100050976, COSV100051987; called by muse, mutect2, varscan2
- CGA | c.12C>T p.Y4= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1290919830, COSV100851659, COSV63644145; called by muse, mutect2
- CLEC14A | c.1062G>T p.T354= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV100643505, COSV60562416; called by muse, mutect2, varscan2
- CLEC6A | c.21T>A p.P7= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV101165619; called by muse, mutect2, varscan2
- CLN3 | c.70C>A p.R24= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100112287; called by muse, mutect2, varscan2
- CNGA3 | c.12C>A p.I4= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs766645136, COSV99736174; called by muse, mutect2, varscan2
- COL24A1 | c.3099T>A p.T1033= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100992962; called by muse, mutect2, varscan2
- CRB1 | c.1620C>A p.G540= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV100957699; called by muse, mutect2, varscan2
- CSDE1 | c.1488A>G p.K496= (on ENST00000358528 / NM_001007553.3; = p.K465= on NM_007158.6) | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV99794193; called by muse, mutect2, varscan2
- CSMD3 | c.4062T>C p.C1354= (on ENST00000297405 / NM_001363185.1; = p.C1250= on NM_052900.3) | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV52234978; called by muse, mutect2, varscan2
- CSMD3 | c.1917G>T p.L639= (on ENST00000297405 / NM_001363185.1; = p.L535= on NM_052900.3) | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as COSV99826464; called by muse, mutect2, varscan2
- CSNK1G3 | c.1122G>A p.Q374= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100631346; called by muse, mutect2, varscan2
- CTPS1 | c.1281G>C p.T427= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV101009283; called by muse, mutect2, varscan2
- CYP2A13 | c.210C>T p.T70= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as COSV100386652; called by muse, mutect2, varscan2
- CYP2C19 | c.1345C>T p.L449= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV100990259; called by muse, mutect2, varscan2
- CYP4A11 | c.1071T>C p.D357= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV100152210; called by muse, mutect2, varscan2
- DCHS1 | c.9714C>T p.P3238= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100197204; called by muse, mutect2, varscan2
- DGKI | c.1413C>A p.L471= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV55970926, COSV99932707; called by muse, mutect2, varscan2
- DMBX1 | c.873G>C p.P291= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100760675, COSV63602570; called by muse, mutect2, varscan2
- DMGDH | c.2082G>T p.L694= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV99668540; called by muse, mutect2, varscan2
- DNAH10 | c.2910C>T p.P970= (on ENST00000409039; = p.P909= on NM_207437.3) | Silent (SNP) | VAF 71/292 reads (24%) | catalogued as COSV101292033; called by muse, mutect2, varscan2
- DNAH3 | c.7161G>T p.V2387= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as COSV99765320; called by muse, mutect2, varscan2
- DNAH5 | c.7944G>A p.A2648= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as rs942441992, COSV54253137; called by muse, mutect2, varscan2
- DOP1B | c.2703G>T p.R901= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs939916306, COSV101215103; called by muse, mutect2, varscan2
- DPF3 | c.654T>A p.A218= | Silent (SNP) | VAF 63/145 reads (43%) | catalogued as COSV100818435; called by muse, mutect2, varscan2
- DPPA4 | c.286C>A p.R96= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as COSV100169242; called by muse, mutect2, varscan2
- DSCAM | c.2748A>T p.T916= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV101259253; called by muse, mutect2, varscan2
- DUSP22 | c.429C>G p.V143= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as rs1363181352, COSV100739449; called by muse, mutect2, varscan2
- FAM122A | c.63G>C p.A21= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99598103; called by muse, mutect2, varscan2
- FAM171A1 | c.1131G>C p.L377= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs746927485, COSV100968089; called by muse, mutect2, varscan2
- FAR1 | c.789A>T p.R263= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100701506; called by muse, mutect2, varscan2
- FEZF1 | c.1231A>C p.R411= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as COSV100484423; called by muse, mutect2, varscan2
- FEZF1 | c.393G>C p.L131= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100484424; called by muse, mutect2
- FN1 | c.3117C>G p.P1039= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV100115862, COSV100116300; called by muse, mutect2
- GABRP | c.417C>A p.L139= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV99516615; called by muse, mutect2, varscan2
- GIMAP8 | c.555C>T p.L185= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV56234276; called by muse, mutect2, varscan2
- GP2 | c.744G>A p.L248= (on ENST00000381362 / NM_001007240.3; = p.L245= on NM_001502.4) | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV100221288, COSV56893842; called by muse, mutect2, varscan2
- GPR149 | c.2001G>A p.G667= | Silent (SNP) | VAF 87/212 reads (41%) | catalogued as COSV101078152, COSV67668118; called by muse, mutect2, varscan2
- GPR158 | c.1116G>A p.R372= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as COSV66269325; called by muse, mutect2, varscan2
- GPR50 | c.639C>A p.T213= | Silent (SNP) | VAF 31/149 reads (21%) | catalogued as COSV99505739; called by muse, mutect2, varscan2
- GREM2 | c.375C>A p.P125= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as COSV58953097; called by muse, mutect2, varscan2
- GRID2 | c.582T>C p.D194= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV99938035; called by muse, mutect2, varscan2
- GRIN2D | c.3361C>T p.L1121= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV99474241; called by muse, mutect2
- GRIN3A | c.2625T>A p.I875= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100701384; called by muse, mutect2, varscan2
- GRM8 | c.2208C>A p.A736= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100281103; called by muse, mutect2, varscan2
- GUCY2C | c.1818C>A p.S606= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as COSV99663299; called by muse, mutect2, varscan2
- GYG1 | c.246C>A p.V82= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as COSV99936728; called by muse, mutect2, varscan2
- HEPH | c.2655A>G p.A885= (on ENST00000343002; = p.A618= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100294232; called by muse, mutect2, varscan2
- HEY2 | c.522C>T p.A174= | Silent (SNP) | VAF 51/221 reads (23%) | catalogued as rs1562712118, COSV100856304; called by muse, mutect2, varscan2
- HOXA3 | c.354G>T p.A118= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100415327; called by muse, mutect2
- HOXB9 | c.723G>A p.K241= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV100239460; called by muse, mutect2, varscan2
- HTN3 | c.129T>C p.Y43= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs768439835, COSV101126156; called by muse, mutect2, varscan2
- HTR5A | c.636G>T p.P212= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV55287343, COSV99839482; called by muse, mutect2, varscan2
- IFIH1 | c.2070G>T p.L690= | Silent (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2
- IGHG2 | c.831G>A p.L277= | Silent (SNP) | VAF 51/587 reads (9%) | called by muse, mutect2
- IGHV1-45 | c.24C>A p.L8= | Silent (SNP) | VAF 17/98 reads (17%) | called by muse, mutect2, varscan2
- IGHV3-64 | c.18G>T p.L6= | Silent (SNP) | VAF 39/205 reads (19%) | called by muse, mutect2, varscan2
- IL19 | c.270C>T p.F90= | Silent (SNP) | VAF 61/275 reads (22%) | catalogued as rs1268416541, COSV99536219; called by muse, mutect2, varscan2
- ITGA2 | c.624G>A p.K208= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV99670322; called by muse, mutect2
- ITSN2 | c.2517T>A p.S839= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV100742806; called by muse, mutect2, varscan2
- KCNH4 | c.2553G>A p.L851= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV99236825; called by muse, mutect2, varscan2
- KLHDC1 | c.54C>G p.A18= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV99364606; called by muse, mutect2, varscan2
- KLK2 | c.267G>A p.R89= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV100319862; called by muse, mutect2, varscan2
- KRT81 | c.81C>T p.I27= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100576937; called by muse, mutect2, varscan2
- LAMA3 | c.7141A>C p.R2381= (on ENST00000313654 / NM_198129.4; = p.R772= on NM_000227.6) | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV99334004; called by muse, mutect2, varscan2
- LARP1 | c.1635G>T p.L545= (on ENST00000518297 / NM_033551.3; = p.L468= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100303512; called by muse, mutect2, varscan2
- LARP6 | c.1089G>T p.P363= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV100150721; called by muse, mutect2, varscan2
- LMX1B | c.186C>T p.P62= | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as rs757937784, CD012852, COSV100826935; called by muse, mutect2, varscan2
- LRFN5 | c.54G>A p.Q18= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV53271845; called by muse, mutect2, varscan2
- LRRC7 | c.2685T>A p.A895= (on ENST00000651989 / NM_001370785.2; = p.A862= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV99224808; called by muse, mutect2, varscan2
- MAG | c.1812A>G p.K604= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as rs1282972658, COSV100727632; called by muse, mutect2, varscan2
- MAGEB1 | c.822G>A p.P274= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as rs772666054, COSV100974859; called by muse, mutect2, varscan2
- MANEA | c.291A>G p.P97= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV62590937; called by muse, mutect2, varscan2
- MAP3K7 | c.1701G>C p.L567= (on ENST00000369329 / NM_145331.3; = p.L540= on NM_003188.4) | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100997450; called by muse, mutect2, varscan2
- MASP2 | c.291G>T p.T97= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV101280063; called by muse, mutect2, varscan2
- MMP14 | c.471G>T p.L157= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100313954; called by muse, mutect2, varscan2
- MPO | c.561G>T p.T187= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs749743427, COSV99832324; called by muse, mutect2, varscan2
- MT1E | c.156G>T p.G52= | Silent (SNP) | VAF 36/196 reads (18%) | catalogued as COSV100042278; called by muse, mutect2, varscan2
- MYH2 | c.5466G>A p.E1822= | Silent (SNP) | VAF 33/142 reads (23%) | catalogued as rs755214642, COSV55438915; called by muse, mutect2, varscan2
- MYO18B | c.7611T>A p.G2537= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100122774; called by muse, mutect2, varscan2
- MYO6 | c.801A>T p.S267= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1338799545, COSV100889302; called by muse, mutect2
- NEFH | c.2139G>A p.K713= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as COSV100151306; called by muse, varscan2
- NKAP | c.291G>T p.S97= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV101004186; called by muse, mutect2, varscan2
- NLRP10 | c.1560C>A p.I520= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100149505; called by muse, mutect2, varscan2
- NLRP11 | c.2256C>T p.T752= | Silent (SNP) | VAF 47/174 reads (27%) | catalogued as COSV100789647; called by muse, mutect2, varscan2
- NLRP3 | c.2922G>T p.L974= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV100275351; called by muse, mutect2
- NR1H3 | c.903G>A p.E301= | Silent (SNP) | VAF 44/210 reads (21%) | catalogued as COSV101269722; called by muse, mutect2, varscan2
- OPN3 | c.402G>T p.V134= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100087095; called by muse, mutect2, varscan2
- OR10C1 | c.117C>G p.T39= (on ENST00000622521; = p.T37= on NM_013941.3) | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as COSV101010799; called by muse, mutect2, varscan2
- OR10K1 | c.168T>C p.H56= | Silent (SNP) | VAF 41/178 reads (23%) | catalogued as rs371933530; called by muse, mutect2, varscan2
- OR10P1 | c.609C>A p.A203= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV100548117; called by muse, mutect2, varscan2
- OR10S1 | c.588C>A p.P196= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV101602447, COSV101602458; called by muse, mutect2, varscan2
- OR13F1 | c.714T>C p.F238= | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as COSV100594693; called by muse, mutect2
- OR2T33 | c.486G>T p.L162= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs1401423258, COSV100531654; called by muse, mutect2, varscan2
- OR2T33 | c.123C>T p.S41= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV100531655; called by muse, mutect2, varscan2
- OR4L1 | c.732C>T p.I244= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as COSV100235581; called by muse, mutect2, varscan2
- OR4N2 | c.708C>A p.A236= | Silent (SNP) | VAF 59/269 reads (22%) | catalogued as COSV100269416; called by muse, mutect2, varscan2
- OR51F2 | c.144G>C p.L48= | Silent (SNP) | VAF 58/201 reads (29%) | catalogued as COSV100437930; called by muse, mutect2, varscan2
- OR9I1 | c.627C>A p.A209= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100109447; called by muse, mutect2, varscan2
- PCDHB11 | c.600G>C p.L200= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV53380005; called by muse, mutect2, varscan2
- PCDHB4 | c.2223C>T p.T741= | Silent (SNP) | VAF 62/218 reads (28%) | catalogued as COSV52027626; called by muse, mutect2, varscan2
- PCLO | c.14016A>T p.S4672= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100428031; called by muse, mutect2, varscan2
- PCSK5 | c.5355C>G p.P1785= | Silent (SNP) | VAF 15/127 reads (12%) | catalogued as COSV101377289; called by muse, mutect2, varscan2
- PHACTR4 | c.1845A>G p.E615= (on ENST00000373839 / NM_001350159.2; = p.E625= on NM_023923.4) | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV100868405; called by muse, mutect2, varscan2
- PKHD1 | c.3780G>C p.A1260= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100581450, COSV61868004, COSV61887362; called by muse, mutect2, varscan2
- PLCXD3 | c.420G>A p.V140= | Silent (SNP) | VAF 48/141 reads (34%) | catalogued as COSV100125311; called by muse, mutect2, varscan2
- PLXNA4 | c.4113G>T p.T1371= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV100322749; called by muse, mutect2, varscan2
- PRKCA | c.1797G>A p.R599= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV101151239, COSV101151271; called by muse, mutect2, varscan2
- PRPF3 | c.1497C>T p.H499= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs557184419, COSV61395079; called by muse, mutect2, varscan2
- PTPRU | c.891T>C p.A297= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV60539151; called by muse, mutect2, varscan2
- RAPH1 | c.2757C>A p.P919= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as rs1243822449, COSV99863445; called by muse, mutect2, varscan2
- RBM33 | c.1026G>A p.Q342= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV100265211; called by muse, mutect2, varscan2
- RGMB | c.999G>C p.L333= (on ENST00000513185 / NM_001366508.1; = p.L374= on NM_001012761.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100374746; called by muse, mutect2, varscan2
- RGS7BP | c.367C>A p.R123= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs202031234, COSV100470469, COSV61834860; called by muse, mutect2, varscan2
- RTP5 | c.1287C>A p.V429= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100574674; called by muse, mutect2, varscan2
- RYR2 | c.9702C>G p.V3234= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV100768354; called by muse, mutect2, varscan2
- SCG3 | c.348G>T p.L116= | Silent (SNP) | VAF 37/146 reads (25%) | catalogued as COSV55020140; called by muse, mutect2, varscan2
- SCTR | c.1059C>A p.I353= | Silent (SNP) | VAF 23/140 reads (16%) | catalogued as COSV99191521; called by muse, mutect2, varscan2
- SDR9C7 | c.691C>A p.R231= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as COSV99524518; called by muse, mutect2, varscan2
- SELP | c.1326C>T p.V442= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV99739149; called by muse, mutect2, varscan2
- SHOC2 | c.222G>T p.R74= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV99509941; called by muse, mutect2, varscan2
- SIGLECL1 | c.453G>A p.A151= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as rs369648100; called by muse, mutect2, varscan2
- SLC22A12 | c.1548C>A p.P516= | Silent (SNP) | VAF 38/191 reads (20%) | catalogued as COSV100327396; called by muse, mutect2, varscan2
- SPTBN5 | c.3765G>T p.R1255= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100310818; called by muse, mutect2, varscan2
- SRPX2 | c.246C>T p.S82= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV100883989; called by muse, mutect2, varscan2
- SS18 | c.1158G>A p.Q386= (on ENST00000415083 / NM_001007559.3; = p.Q355= on NM_005637.3) | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV52264712; called by muse, mutect2, varscan2
- SULF2 | c.801C>G p.P267= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100737023, COSV100737532; called by muse, mutect2, varscan2
- SYNE1 | c.16479G>T p.L5493= (on ENST00000367255 / NM_182961.4; = p.L5422= on NM_033071.3) | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV99555117; called by muse, mutect2, varscan2
- TACR3 | c.462C>G p.G154= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV100510145; called by muse, mutect2, varscan2
- TAPBP | c.198C>T p.L66= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV56474528; called by muse, mutect2
- TAS1R2 | c.768C>T p.R256= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs1402760294, COSV100946144; called by muse, mutect2, varscan2
- TENM1 | c.810T>C p.S270= | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as COSV100949231; called by muse, mutect2, varscan2
- TENM1 | c.33T>A p.P11= | Silent (SNP) | VAF 41/146 reads (28%) | catalogued as COSV100949233; called by muse, mutect2, varscan2
- TEX14 | c.3474A>G p.Q1158= (on ENST00000240361 / NM_001201457.2; = p.Q1112= on NM_031272.5) | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV99541590; called by muse, mutect2, varscan2
- TLL2 | c.1068G>A p.Q356= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs374275574, COSV100780155; called by muse, mutect2, varscan2
- TMCO4 | c.1305G>T p.A435= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as COSV99615888, COSV99616879; called by muse, mutect2, varscan2
- TMEM108 | c.1566G>A p.V522= | Silent (SNP) | VAF 15/513 reads (3%) | catalogued as COSV100418425; called by muse, mutect2
- TMEM175 | c.459G>C p.V153= | Silent (SNP) | VAF 29/204 reads (14%) | catalogued as COSV99297548; called by muse, mutect2
- TMEM222 | c.573C>T p.F191= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as COSV100929942; called by muse, mutect2, varscan2
- TNN | c.492C>A p.P164= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs779523080, COSV53427233, COSV99511229; called by muse, mutect2, varscan2
- TPH2 | c.903C>T p.Y301= | Silent (SNP) | VAF 45/200 reads (23%) | catalogued as COSV100421942; called by muse, mutect2, varscan2
- TRIM48 | c.636G>T p.G212= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV101338204; called by muse, mutect2, varscan2
- TRPA1 | c.972A>G p.L324= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs375268460; called by muse, mutect2, varscan2
- TRPM6 | c.4026C>A p.G1342= | Silent (SNP) | VAF 111/247 reads (45%) | catalogued as COSV100665379, COSV100665560; called by muse, mutect2, varscan2
- TTN | c.1671G>A p.Q557= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV100597262; called by muse, mutect2, varscan2
- TUBGCP2 | c.2529T>C p.Y843= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV99427261; called by muse, mutect2, varscan2
- TYROBP | c.129G>T p.L43= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV99385515; called by muse, mutect2, varscan2
- UTRN | c.8538C>A p.T2846= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV100838205, COSV100838456; called by muse, mutect2, varscan2
- VAC14 | c.2214C>G p.S738= | Silent (SNP) | VAF 32/195 reads (16%) | catalogued as COSV99934206; called by muse, mutect2, varscan2
- VCPIP1 | c.3663C>T p.H1221= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV100125372; called by muse, mutect2, varscan2
- XRCC4 | c.915A>C p.L305= (on ENST00000338635 / NM_022406.4; = p.L303= on NM_003401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/126 reads (14%) | catalogued as COSV99982155; called by muse, mutect2, varscan2
- YIPF7 | c.222C>A p.S74= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100274355; called by muse, mutect2, varscan2
27 further variants in this file (0 protein-altering or splice-affecting, 8 silent, 19 other) are not listed here.
